Somatic mutation profile of tumor specimen TCGA-AO-A12A-01A (aliquot TCGA-AO-A12A-01A-21D-A10Y-09) from TCGA case TCGA-AO-A12A, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.7 years (17,420 days).
Specimen TCGA-AO-A12A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa31ba87-1903-4ad5-9e33-9929f550fe1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A12A-10A (Blood Derived Normal), aliquot TCGA-AO-A12A-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ca103fd-58e0-49be-a3c5-d81d2fbae08a

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 40/110 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ALPK2 | c.3933A>T p.R1311S | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.286); catalogued as COSV64497930; called by muse, mutect2, varscan2
- CATSPERD | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as rs141589760; called by muse, mutect2, varscan2
- FAM47C | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.106); catalogued as rs377326539, COSV100792323, COSV63724457; called by muse, mutect2, varscan2
- FMN1 | c.3587G>A p.R1196K (on ENST00000616417 / NM_001277313.2; = p.R973K on NM_001103184.4) | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV57930716; called by muse, mutect2
- GATA3 | c.922-3_922-2del p.X308_splice | Splice Site (DEL) | VAF 25/87 reads (29%) | catalogued as rs763236375, COSV60515023; called by mutect2, pindel, varscan2
- KDM6A | c.3356T>C p.L1119P | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV65047090; called by muse, mutect2, varscan2
- MAP1S | c.3073G>A p.A1025T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs371306436; called by muse, mutect2, varscan2
- OTOGL | c.5807G>T p.G1936V (on ENST00000547103; = p.G1927V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.175); catalogued as COSV54021411, COSV54024952; called by muse, mutect2, varscan2
- TEC | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs780984861, COSV101202556; called by muse, mutect2, varscan2
- THADA | c.2102A>T p.Y701F | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.793); catalogued as COSV100368035; called by muse, mutect2
- ZNF93 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs1278207913, COSV59379301; called by muse, mutect2, varscan2
- CWF19L2 | c.953dup p.Y318* | Nonsense Mutation (INS) | VAF 45/324 reads (14%) | called by mutect2, pindel, varscan2
- MEGF11 | c.1414C>A p.Q472K | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLRT2 | c.1188G>A p.T396= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs200412416, COSV58143947; called by muse, mutect2, varscan2
- GRIA1 | c.873G>A p.A291= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs749706041, COSV53627489; called by muse, mutect2, varscan2
- POLH | c.876G>A p.E292= | Silent (SNP) | VAF 18/163 reads (11%) | catalogued as COSV64781233; called by muse, mutect2, varscan2
- PRR16 | c.345G>A p.T115= (on ENST00000407149 / NM_001300783.2; = p.T92= on NM_016644.2) | Silent (SNP) | VAF 7/127 reads (6%) | catalogued as rs1052878559, COSV65407469; called by muse, mutect2
